Somatic mutation profile of cancer-model specimen HCM-CSHL-0058-C34-85C (3D Organoid; aliquot HCM-CSHL-0058-C34-85C-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0058-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 82.8 years (30,226 days).
Specimen HCM-CSHL-0058-C34-85C: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f93288b-2069-4a76-8aa7-ebff14fae00b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0058-C34-10A (Blood Derived Normal), aliquot HCM-CSHL-0058-C34-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac9a8c8c-0a0d-4c70-8604-3d49d6ae440d

The open-access MAF lists 186 somatic variants for this specimen: 121 protein-altering or splice-affecting, 38 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 38, Intron 11, Nonsense Mutation 11, 5'UTR 7, Splice Site 4, 3'UTR 3, 3'Flank 2, RNA 2, 5'Flank 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 45/338 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRA1 | c.838G>T p.G280C | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV101192706; called by muse, mutect2
- AKAP9 | c.3599C>T p.S1200F | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as COSV100662192; called by muse, mutect2
- APC2 | c.3655G>A p.A1219T | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as rs1375738294; called by muse, mutect2
- ATP2A2 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs866972164; called by muse, mutect2
- BTBD7 | c.2846C>G p.S949* | Nonsense Mutation (SNP) | VAF 11/349 reads (3%) | catalogued as COSV58288247; called by muse, mutect2
- CAMSAP1 | c.4217C>G p.S1406C | Missense Mutation (SNP) | VAF 14/315 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV56724143; called by muse, mutect2
- CD1B | c.827G>C p.G276A | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748373854, COSV63803909; called by muse, mutect2
- CDC73 | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 21/450 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.301); catalogued as COSV100813741; called by muse, mutect2
- CHRNB2 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 20/449 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as rs1215936429, COSV63807684; called by muse, mutect2
- DUOX2 | c.3916G>A p.A1306T | Missense Mutation (SNP) | VAF 32/564 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs750364813, COSV66534315; called by muse, mutect2
- GBP2 | c.41T>C p.I14T | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs202090771, COSV65070215; called by muse, mutect2
- GDF5 | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.058); catalogued as rs1309803942; called by muse, mutect2
- GPA33 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs375619086; called by muse, mutect2
- GRM1 | c.2681C>A p.S894* | Nonsense Mutation (SNP) | VAF 77/378 reads (20%) | catalogued as COSV99269155; called by muse, mutect2, varscan2
- INHBA | c.615G>T p.L205F | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.147); catalogued as COSV54220330, COSV99066567; called by muse, mutect2
- ITPR2 | c.1249-2A>G p.X417_splice | Splice Site (SNP) | VAF 8/73 reads (11%) | catalogued as rs1565689068; called by mutect2, varscan2
- MBLAC2 | c.52T>C p.W18R | Missense Mutation (SNP) | VAF 23/376 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57302536; called by muse, mutect2
- MDC1 | c.2957C>T p.S986F | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1185774203, COSV64524871; called by muse, mutect2
- MYH2 | c.4199C>T p.A1400V | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs770023922; ClinVar: uncertain significance; called by muse, mutect2
- MYO18B | c.5051C>T p.A1684V | Missense Mutation (SNP) | VAF 47/370 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1242602241; called by muse, mutect2, varscan2
- N4BP2L2 | c.620A>G p.Y207C | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV57230458; called by muse, mutect2, varscan2
- NF2 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 20/401 reads (5%) | catalogued as CM981386, COSV58521244, COSV58525309; called by muse, mutect2
- NT5DC4 | c.395C>A p.T132N | Missense Mutation (SNP) | VAF 15/402 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1479236828; called by muse, mutect2
- OR5T3 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs780402245, COSV57381889; called by muse, mutect2
- PKHD1 | c.4324C>T p.L1442F | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.617); catalogued as COSV61885116; called by muse, mutect2
- PRB4 | c.100G>T p.G34* | Nonsense Mutation (SNP) | VAF 24/249 reads (10%) | catalogued as COSV99686739; called by muse, mutect2, varscan2
- PREP | c.1729C>G p.R577G (on ENST00000369110; = p.R643G on NM_002726.5) | Missense Mutation (SNP) | VAF 21/295 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64873128; called by muse, mutect2
- RANBP6 | c.799C>G p.L267V | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs748055944; called by muse, mutect2, varscan2
- RBM10 | c.1873G>T p.G625* | Nonsense Mutation (SNP) | VAF 28/167 reads (17%) | catalogued as COSV61310019; called by muse, mutect2, varscan2
- SECISBP2L | c.715A>G p.M239V | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs765230609; called by muse, mutect2
- SMARCC2 | c.3572C>T p.P1191L | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as rs1218565699; called by muse, mutect2
- SOGA3 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 27/341 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64106260; called by muse, mutect2
- SSU72P8 | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV66361273; called by muse, mutect2
- STAG2 | c.1736del p.S579Lfs*2 | Frame Shift Del (DEL) | VAF 25/70 reads (36%) | catalogued as COSV54363033; called by mutect2, pindel, varscan2
- TAF1A | c.776T>C p.V259A | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV61917808; called by muse, mutect2, varscan2
- TNS1 | c.4636A>G p.N1546D | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.89); catalogued as rs1248701399; called by muse, mutect2
- TPO | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 31/449 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.194); catalogued as COSV100222346, COSV61110138; called by muse, mutect2
- TPR | c.1460G>C p.R487P | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV66600044; called by muse, mutect2
- USF1 | c.532A>G p.I178V | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs759252432, COSV57040748; called by muse, mutect2, varscan2
- WDR81 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 13/215 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs1293736314; called by muse, mutect2
- WWTR1 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 11/213 reads (5%) | catalogued as COSV62291505; called by muse, mutect2
- ZMYND10 | c.327C>A p.H109Q | Missense Mutation (SNP) | VAF 18/347 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51602012; called by muse, mutect2
- ZNF232 | c.980G>C p.G327A | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1292671430; called by muse, mutect2
- ZNF716 | c.546G>T p.K182N | Missense Mutation (SNP) | VAF 12/261 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as COSV101348735; called by muse, mutect2
- AGO1 | c.1709G>T p.G570V | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AKT2 | c.1264-2A>T p.X422_splice | Splice Site (SNP) | VAF 34/606 reads (6%) | called by muse, mutect2
- ARHGAP33 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATXN7L2 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.62); called by muse, mutect2
- BCHE | c.1079A>G p.Y360C | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- BICDL2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 20/440 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2
- BRPF1 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2
- CADM2 | c.1105C>G p.L369V (on ENST00000407528 / NM_001167674.2; = p.L371V on NM_153184.4) | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2
- CCDC39 | c.1519A>T p.K507* | Nonsense Mutation (SNP) | VAF 17/327 reads (5%) | called by muse, mutect2
- CDX4 | c.550C>G p.Q184E | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CHRM5 | c.1427T>G p.L476R | Missense Mutation (SNP) | VAF 21/243 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- CNTN2 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2
- COL5A3 | c.1201-2A>T p.X401_splice | Splice Site (SNP) | VAF 12/141 reads (9%) | called by muse, mutect2
- DAB2IP | c.2651G>C p.R884P (on ENST00000408936; = p.R856P on NM_032552.3) | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- DPH2 | c.863C>G p.A288G | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2
- DSPP | c.906A>T p.K302N | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2
- EGFLAM | c.1433G>C p.R478T | Missense Mutation (SNP) | VAF 13/361 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ELAC1 | c.118G>C p.G40R | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ELK4 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EMSY | c.3161A>T p.Q1054L | Missense Mutation (SNP) | VAF 23/377 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- EVC | c.2558A>G p.Q853R | Missense Mutation (SNP) | VAF 23/524 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- FAM161B | c.110C>A p.T37N | Missense Mutation (SNP) | VAF 16/438 reads (4%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2
- FNDC3B | c.2599C>G p.L867V | Missense Mutation (SNP) | VAF 13/450 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.222); called by muse, mutect2
- FSIP2 | c.8440C>G p.Q2814E | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- GJC2 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 53/749 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- INAVA | c.1841T>G p.V614G | Missense Mutation (SNP) | VAF 10/301 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- IQGAP1 | c.2839G>C p.D947H | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); called by muse, mutect2
- KIF2C | c.1211T>C p.I404T | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KTN1 | c.3988C>T p.Q1330* (on ENST00000395314 / NM_001271014.2; = p.Q1273* on NM_004986.4) | Nonsense Mutation (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- LAMA2 | c.7104C>A p.F2368L | Missense Mutation (SNP) | VAF 18/407 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRCOL1 | c.393C>A p.H131Q | Missense Mutation (SNP) | VAF 11/200 reads (6%) | PolyPhen benign (0.001); called by muse, mutect2
- LTK | c.1355A>G p.K452R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LYST | c.4913C>T p.S1638L | Missense Mutation (SNP) | VAF 10/239 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2
- MARCHF11 | c.602T>A p.L201Q | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); called by muse, mutect2
- MFSD6 | c.1369A>G p.M457V | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- MS4A6E | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- MUC16 | c.12407C>T p.T4136I | Missense Mutation (SNP) | VAF 7/189 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.112); called by muse, mutect2
- MYH11 | c.3988C>A p.Q1330K | Missense Mutation (SNP) | VAF 36/652 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.88); called by muse, mutect2
- NKD1 | c.628C>G p.P210A | Missense Mutation (SNP) | VAF 7/181 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.08); called by muse, mutect2
- NKTR | c.3143A>G p.N1048S | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- NPHS1 | c.2975C>A p.P992Q | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- NXPE1 | c.1109-1G>C p.X370_splice (on ENST00000424269; = p.X228_splice on NM_152315.5) | Splice Site (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- OR2H1 | c.375C>A p.C125* | Nonsense Mutation (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- OR5H15 | c.358T>A p.Y120N | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- PCDHB6 | c.1302C>G p.S434R | Missense Mutation (SNP) | VAF 36/588 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); called by muse, mutect2
- PCDHGA2 | c.2105G>C p.C702S | Missense Mutation (SNP) | VAF 32/598 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); called by muse, mutect2
- PCYT1A | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 13/386 reads (3%) | called by muse, mutect2
- PER2 | c.3556G>A p.E1186K | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PIP4K2C | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.18); called by muse, mutect2
- PLEC | c.5488G>A p.E1830K (on ENST00000322810 / NM_201380.4; = p.E1720K on NM_000445.5) | Missense Mutation (SNP) | VAF 30/544 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- POTEC | c.395G>C p.R132T | Missense Mutation (SNP) | VAF 31/802 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); called by muse, mutect2
- PRDM2 | c.3442G>T p.D1148Y | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PTCH1 | c.3110C>T p.A1037V | Missense Mutation (SNP) | VAF 36/390 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.241); called by muse, mutect2
- RHAG | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 18/369 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- RP1L1 | c.1649G>T p.G550V | Missense Mutation (SNP) | VAF 43/546 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.346); called by muse, mutect2
- RPAP3 | c.1336A>T p.T446S | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2
- SERPINF1 | c.1039A>G p.T347A | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.057); called by muse, mutect2
- SLC10A2 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 20/406 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.267); called by muse, mutect2
- SLC10A3 | c.1249G>T p.V417F | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC5A6 | c.363C>G p.F121L | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); called by muse, mutect2
- SLC5A9 | c.1378A>C p.I460L | Missense Mutation (SNP) | VAF 12/313 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.074); called by muse, mutect2
- SPTY2D1 | c.1066A>G p.M356V | Missense Mutation (SNP) | VAF 19/405 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- SS18 | c.1238A>G p.Y413C (on ENST00000415083 / NM_001007559.3; = p.Y382C on NM_005637.3) | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- SYNE1 | c.7589G>T p.W2530L (on ENST00000367255 / NM_182961.4; = p.W2537L on NM_033071.3) | Missense Mutation (SNP) | VAF 11/270 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2
- TICAM1 | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TMEM236 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 20/592 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- TPH2 | c.1217G>T p.C406F | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2
- TRAV22 | c.190A>C p.I64L | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.26); called by muse, mutect2
- TRPM1 | c.2610C>A p.S870R | Missense Mutation (SNP) | VAF 22/458 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2
- TSKS | c.979A>G p.I327V | Missense Mutation (SNP) | VAF 27/291 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- TSPOAP1 | c.713G>C p.C238S | Missense Mutation (SNP) | VAF 38/534 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- UACA | c.900G>T p.E300D | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2
- WNK1 | c.4522C>T p.Q1508* (on ENST00000315939 / NM_018979.4; = p.Q1261* on NM_014823.3) | Nonsense Mutation (SNP) | VAF 24/274 reads (9%) | called by muse, mutect2
- ZFP2 | c.311G>T p.C104F | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZHX3 | c.911G>A p.S304N | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.298); called by muse, mutect2
- ZPLD1 | c.306G>T p.E102D (on ENST00000466937 / NM_001329788.1; = p.E118D on NM_175056.2) | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.137); called by muse, mutect2
- ACTB | c.30C>T p.V10= | Silent (SNP) | VAF 47/485 reads (10%) | catalogued as rs768066226, COSV59320045; called by muse, mutect2
- ADAMTS3 | c.3168C>T p.T1056= | Silent (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- ARMC1 | c.558A>G p.R186= | Silent (SNP) | VAF 28/283 reads (10%) | called by muse, mutect2, varscan2
- ARMC6 | c.1357C>T p.L453= (on ENST00000392336; = p.L428= on NM_033415.4) | Silent (SNP) | VAF 23/268 reads (9%) | called by muse, mutect2
- CAD | c.1269G>A p.L423= | Silent (SNP) | VAF 23/198 reads (12%) | catalogued as COSV53027818, COSV53028297; called by muse, mutect2, varscan2
- CHRNB1 | c.85C>A p.R29= | Silent (SNP) | VAF 26/482 reads (5%) | called by muse, mutect2
- DLGAP3 | c.754C>A p.R252= | Silent (SNP) | VAF 28/284 reads (10%) | called by muse, mutect2
- EGR3 | c.339G>T p.V113= | Silent (SNP) | VAF 13/312 reads (4%) | called by muse, mutect2
- FAM160A2 | c.1791A>C p.L597= (on ENST00000449352 / NM_001098794.2; = p.L611= on NM_032127.4) | Silent (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- FEZ1 | c.853C>A p.R285= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as rs1347208502, COSV54026913; called by muse, mutect2
- FOXL1 | c.132C>A p.A44= | Silent (SNP) | VAF 32/455 reads (7%) | called by muse, mutect2
- IDH1 | c.375A>G p.V125= | Silent (SNP) | VAF 12/220 reads (5%) | catalogued as COSV61625559; called by muse, mutect2
- KRT6C | c.1002C>T p.I334= | Silent (SNP) | VAF 49/668 reads (7%) | catalogued as rs369806166; called by muse, mutect2
- LRIT3 | c.517C>T p.L173= | Silent (SNP) | VAF 9/159 reads (6%) | called by muse, mutect2
- MED25 | c.960C>T p.F320= | Silent (SNP) | VAF 18/282 reads (6%) | called by muse, mutect2
- MYO1E | c.1056G>T p.R352= | Silent (SNP) | VAF 24/306 reads (8%) | called by muse, mutect2
- MYO1F | c.2175G>A p.L725= | Silent (SNP) | VAF 34/548 reads (6%) | called by muse, mutect2
- NIBAN2 | c.1464G>T p.R488= | Silent (SNP) | VAF 20/212 reads (9%) | called by muse, mutect2
- NRG1 | c.552G>A p.E184= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as rs1224695823; called by muse, mutect2
- NT5DC4 | c.396C>A p.T132= | Silent (SNP) | VAF 15/407 reads (4%) | called by muse, mutect2
- OR5H2 | c.219T>C p.F73= | Silent (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- PCDHA10 | c.1899G>T p.T633= | Silent (SNP) | VAF 17/255 reads (7%) | catalogued as rs782434773, COSV56477279; called by muse, mutect2
- PCDHA11 | c.2121C>A p.S707= | Silent (SNP) | VAF 18/370 reads (5%) | called by muse, mutect2
- PRUNE2 | c.5661T>C p.F1887= | Silent (SNP) | VAF 25/246 reads (10%) | called by muse, mutect2, varscan2
- RAD50 | c.2505A>G p.K835= | Silent (SNP) | VAF 14/284 reads (5%) | catalogued as rs996373843; ClinVar: likely benign; called by muse, mutect2
- RXFP3 | c.927C>A p.A309= | Silent (SNP) | VAF 27/291 reads (9%) | called by muse, mutect2
- SMAD6 | c.570G>A p.T190= | Silent (SNP) | VAF 11/235 reads (5%) | catalogued as rs1338246502; ClinVar: likely benign; called by muse, mutect2
- SNX29 | c.1965G>T p.R655= | Silent (SNP) | VAF 17/320 reads (5%) | called by muse, mutect2
- SPHKAP | c.3891G>T p.G1297= | Silent (SNP) | VAF 11/140 reads (8%) | called by muse, mutect2
- SPOCK2 | c.312G>A p.Q104= | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as COSV58036528; called by muse, mutect2
- SSTR4 | c.867T>C p.D289= | Silent (SNP) | VAF 23/235 reads (10%) | called by muse, mutect2, varscan2
- ST3GAL5 | c.1074C>A p.L358= (on ENST00000377332; = p.L398= on NM_003896.4) | Silent (SNP) | VAF 15/264 reads (6%) | called by muse, mutect2
- SYNE1 | c.22392A>G p.K7464= (on ENST00000367255 / NM_182961.4; = p.K7393= on NM_033071.3) | Silent (SNP) | VAF 11/243 reads (5%) | called by muse, mutect2
- TET1 | c.6162A>T p.L2054= | Silent (SNP) | VAF 28/358 reads (8%) | called by muse, mutect2
- TG | c.1959T>A p.G653= | Silent (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- TNFRSF21 | c.1779C>T p.P593= | Silent (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- ZNF423 | c.732G>A p.S244= (on ENST00000563137 / NM_001379286.1; = p.S236= on NM_015069.4) | Silent (SNP) | VAF 20/318 reads (6%) | catalogued as rs977567436, COSV52176592, COSV52183945; called by muse, mutect2
- ZNF547 | c.423G>T p.P141= | Silent (SNP) | VAF 19/236 reads (8%) | called by muse, mutect2
- ADAD2 | c.419-142G>C | Intron (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- ADGRV1 | c.*18G>A | 3'UTR (SNP) | VAF 16/321 reads (5%) | catalogued as rs368671859; called by muse, mutect2
- ATP11B | c.-34C>G | 5'UTR (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- BLK | c.1030-147G>C | Intron (SNP) | VAF 10/326 reads (3%) | called by muse, mutect2
- BTNL8 | c.862+9G>A | Intron (SNP) | VAF 23/345 reads (7%) | catalogued as rs368569419; called by muse, mutect2
- C19orf12 | chr19:29700174 C>A | 3'Flank (SNP) | VAF 9/186 reads (5%) | called by muse, mutect2
- CCDC162P | n.1841C>T | RNA (SNP) | VAF 6/135 reads (4%) | catalogued as rs1048887594; called by muse, mutect2
- COCH | c.928+27T>C | Intron (SNP) | VAF 26/192 reads (14%) | catalogued as rs917841960; called by muse, mutect2, varscan2
- DNAH14 | c.1033-4614C>A | Intron (SNP) | VAF 11/210 reads (5%) | catalogued as COSV64788756; called by muse, mutect2
- EPHB1 | c.-81G>C | 5'UTR (SNP) | VAF 11/182 reads (6%) | called by muse, mutect2
- FBXL15 | c.-864G>A | 5'UTR (SNP) | VAF 5/89 reads (6%) | catalogued as rs1288912805; called by muse, mutect2
- HAS1 | chr19:51723978 C>T | 5'Flank (SNP) | VAF 11/156 reads (7%) | called by muse, mutect2
- HERC2P2 | n.2997G>C | RNA (SNP) | VAF 36/793 reads (5%) | called by muse, mutect2
- IGFN1 | c.1241+1991G>A | Intron (SNP) | VAF 14/322 reads (4%) | catalogued as rs922921755; called by muse, mutect2
- MS4A6E | c.147+571G>T | Intron (SNP) | VAF 8/95 reads (8%) | catalogued as rs1371150543; called by muse, mutect2, varscan2
- OR2AE1 | c.-6G>T | 5'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- OSCAR | c.*400G>T | 3'UTR (SNP) | VAF 11/294 reads (4%) | catalogued as rs765318712; called by muse, mutect2
- PA2G4 | chr12:56104544 C>A | 5'Flank (SNP) | VAF 28/602 reads (5%) | called by muse, mutect2
- PCDHB6 | chr5:141157700 A>G | 3'Flank (SNP) | VAF 35/890 reads (4%) | called by muse, mutect2
- PKP1 | c.-38C>A | 5'UTR (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- PMS2 | c.*152C>G | 3'UTR (SNP) | VAF 6/169 reads (4%) | called by muse, mutect2
- SCIN | c.200-485G>T | Intron (SNP) | VAF 18/263 reads (7%) | catalogued as rs1475657534; called by muse, mutect2
- SCIN | c.200-484G>T | Intron (SNP) | VAF 18/265 reads (7%) | catalogued as rs1165293304; called by muse, mutect2
- ST3GAL6 | c.-332G>T | 5'UTR (SNP) | VAF 11/301 reads (4%) | called by muse, mutect2
- UGT1A6 | c.862-23334C>T | Intron (SNP) | VAF 30/548 reads (5%) | catalogued as rs373107890; called by muse, mutect2
- UGT1A6 | c.862-11982G>A | Intron (SNP) | VAF 17/331 reads (5%) | called by muse, mutect2
- VIM | c.-39C>T | 5'UTR (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
